Somatic mutation profile of tumor specimen TCGA-D9-A3Z3-06A (aliquot TCGA-D9-A3Z3-06A-11D-A23B-08) from TCGA case TCGA-D9-A3Z3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 39.7 years (14,500 days).
Specimen TCGA-D9-A3Z3-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41698e0e-93db-4b9d-8349-a7ca1bac1267.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D9-A3Z3-10A (Blood Derived Normal), aliquot TCGA-D9-A3Z3-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78eab2e3-7d89-4d6a-a49c-f63ccac286fd

The open-access MAF lists 160 somatic variants for this specimen: 106 protein-altering or splice-affecting, 51 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 51, Intron 2, RNA 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADGRE1 | c.1082A>G p.D361G | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.918); catalogued as rs376805454; called by muse, mutect2, varscan2
- AHCTF1 | c.6395G>A p.S2132N (on ENST00000366508; = p.S2106N on NM_015446.5) | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs989072719, COSV58254527; called by muse, mutect2, varscan2
- AHNAK | c.2830C>T p.P944S | Missense Mutation (SNP) | VAF 116/275 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV57228011; called by muse, mutect2, varscan2
- ANO2 | c.964G>A p.D322N (on ENST00000356134 / NM_001278597.3; = p.D326N on NM_001278596.3) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs781540782, COSV59007575; called by muse, mutect2, varscan2
- AP3B1 | c.1271C>T p.T424I | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1188811427, COSV54891725; called by muse, mutect2
- APOA4 | c.1043G>A p.R348K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as rs1473754050, COSV63361115; called by muse, mutect2, varscan2
- BHMT | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV57153799, COSV57155603; called by muse, mutect2, varscan2
- BOLA1 | c.112A>C p.T38P | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.18); catalogued as COSV100975440; called by muse, mutect2, varscan2
- BOLA1 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV100975441; called by muse, mutect2, varscan2
- C8B | c.1666T>C p.S556P | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV64779373; called by muse, mutect2, varscan2
- CCDC114 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.217); catalogued as rs1419666594, COSV59558469; called by muse, mutect2, varscan2
- CD180 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs150000308, COSV99842143; called by muse, mutect2, varscan2
- CDKL5 | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.054); catalogued as COSV66113068; called by muse, mutect2, varscan2
- CELF6 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV54717345, COSV54718491; called by muse, mutect2, varscan2
- CFAP74 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs748928183, COSV54565390; called by muse, mutect2, varscan2
- CPZ | c.1272G>A p.M424I (on ENST00000360986 / NM_001014447.3; = p.M413I on NM_003652.3) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as COSV59925754; called by muse, mutect2, varscan2
- CREBBP | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.285); catalogued as COSV52138749; called by muse, mutect2, varscan2
- CUL9 | c.5653G>A p.E1885K | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV52733942, COSV99336025; called by muse, mutect2, varscan2
- DEAF1 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV58609136; called by muse, mutect2, varscan2
- DHX40 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.551); catalogued as COSV52069829; called by muse, mutect2, varscan2
- DOCK8 | c.3401C>T p.S1134F | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV101210043; called by muse, mutect2, varscan2
- ELFN2 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV68746306; called by muse, mutect2, varscan2
- EPHB2 | c.1792G>A p.D598N (on ENST00000400191 / NM_001309193.2; = p.D599N on NM_004442.7) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368925967, COSV65866147; called by muse, mutect2, varscan2
- ERCC3 | c.700C>G p.R234G | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV53429608; called by muse, mutect2, varscan2
- ETS1 | c.1066T>G p.W356G | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60097103; called by muse, mutect2, varscan2
- FAM47A | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV60499505; called by muse, varscan2
- FAM47A | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.076); catalogued as COSV60499512; called by muse, varscan2
- FBXO40 | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV57527096; called by muse, mutect2, varscan2
- FCAMR | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61369331; called by muse, mutect2, varscan2
- FLT3 | c.1853C>T p.S618L | Missense Mutation (SNP) | VAF 75/228 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54043841; called by muse, mutect2, varscan2
- FRAS1 | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as rs573458782, COSV53642616; called by muse, mutect2, varscan2
- GMPPB | c.671A>G p.D224G | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100246718; called by muse, mutect2, varscan2
- GNLY | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs201165294, COSV55704507; called by muse, mutect2, varscan2
- GOLIM4 | c.1069C>T p.L357F | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58331702; called by muse, mutect2, varscan2
- GRM3 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 94/214 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64468191; called by muse, mutect2, varscan2
- HNF4A | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as COSV57388527; called by muse, mutect2, varscan2
- IL17A | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs201890924, COSV60684056; called by muse, mutect2, varscan2
- INPPL1 | c.1090+1G>C p.X364_splice | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as COSV53358945; called by muse, mutect2, varscan2
- ITGA7 | c.2744A>G p.N915S (on ENST00000555728; = p.N871S on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as rs768368830, COSV57700423; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1755 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as rs1014696720, COSV54080084; called by muse, mutect2, varscan2
- KIF26B | c.5953G>A p.E1985K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63650576; called by muse, mutect2
- KRTAP10-6 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV59977993; called by muse, mutect2, varscan2
- LAD1 | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV66213206; called by muse, mutect2, varscan2
- LAMA2 | c.5542G>A p.E1848K | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.165); catalogued as rs866002528, COSV70354259; called by muse, mutect2, varscan2
- LCT | c.3287C>T p.A1096V | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1293012007, COSV51556576; called by muse, mutect2, varscan2
- MELK | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as rs2068826, COSV53199766; called by muse, mutect2, varscan2
- MTFMT | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV54979598; called by muse, mutect2, varscan2
- NEB | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.992); catalogued as COSV51133782; called by muse, mutect2, varscan2
- NEURL4 | c.1909A>G p.T637A | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.136); catalogued as COSV59762955; called by muse, mutect2, varscan2
- NKX2-2 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV65820276; called by muse, mutect2, varscan2
- NLRX1 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV52708888; called by muse, mutect2, varscan2
- NSRP1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV55935215; called by muse, mutect2, varscan2
- NUP210 | c.3235C>T p.P1079S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54405251, COSV54412379; called by muse, mutect2, varscan2
- OPTC | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1271135703, COSV58117398; called by muse, mutect2, varscan2
- OR10A3 | c.338T>G p.F113C | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.681); catalogued as COSV62460129; called by muse, mutect2, varscan2
- OR2M4 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs61743231, COSV60708004, COSV60709499; called by muse, mutect2, varscan2
- OR6C65 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs775376507, COSV65568889; called by muse, mutect2, varscan2
- OR6C68 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as COSV65563842, COSV65563872; called by muse, mutect2, varscan2
- PCDHB13 | c.459T>A p.F153L | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.327); catalogued as COSV53400469; called by muse, mutect2, varscan2
- PDK4 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50012344; called by muse, mutect2
- PKD1L1 | c.4405T>A p.F1469I | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV56976440; called by muse, mutect2, varscan2
- PLCZ1 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV56852184; called by muse, mutect2, varscan2
- PPARGC1A | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.604); catalogued as COSV53527442; called by muse, mutect2, varscan2
- PPFIA1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV54140120; called by muse, varscan2
- PRKCQ | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs751468198, COSV54118135; called by muse, mutect2, varscan2
- PRPF8 | c.1051T>A p.Y351N | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV59267271; called by muse, mutect2, varscan2
- PVALB | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as COSV53413163; called by muse, mutect2, varscan2
- RAET1G | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.18); catalogued as COSV66275023; called by muse, mutect2, varscan2
- RCAN2 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs201045399, COSV57815863; called by muse, mutect2, varscan2
- RHBDF2 | c.396G>T p.W132C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV57422509; called by muse, mutect2, varscan2
- RTTN | c.4352T>G p.I1451S | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV55351068; called by muse, mutect2, varscan2
- SEMA4A | c.1811C>T p.T604I | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs777396925, COSV61773899; called by muse, mutect2, varscan2
- SEMA5B | c.1828G>A p.G610R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52106917; called by muse, mutect2, varscan2
- SKIV2L | c.1339C>T p.H447Y | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs778184511, COSV64813904; called by muse, varscan2
- SLC11A1 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1407747739, COSV51919209; called by muse, mutect2, varscan2
- SLC1A3 | c.1181G>A p.G394E | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561243426, COSV54319860; called by muse, mutect2, varscan2
- SND1 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV61248070; called by muse, mutect2, varscan2
- SNX16 | c.790C>T p.H264Y | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV62036590; called by muse, mutect2, varscan2
- SSMEM1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 147/380 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.515); catalogued as rs768395125, COSV52833817; called by muse, mutect2, varscan2
- STAT4 | c.1591G>A p.G531S | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.181); catalogued as COSV61831998; called by muse, mutect2, varscan2
- STK19 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.08); catalogued as COSV61714940; called by muse, mutect2, varscan2
- TECTA | c.2867C>T p.S956F | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV50792925; called by muse, mutect2, varscan2
- TEX15 | c.7570C>T p.P2524S (on ENST00000256246; = p.P2907S on NM_001350162.2) | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV56352701; called by muse, mutect2, varscan2
- TNFRSF21 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs769216892, COSV57281117, COSV57284525; called by muse, mutect2, varscan2
- TP63 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs1560281511, COSV53200593; called by muse, mutect2
- TPR | c.4343T>G p.L1448R | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66604458; called by muse, mutect2, varscan2
- TSHZ2 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61587671; called by muse, mutect2, varscan2
- TTN | c.72727G>A p.E24243K (on ENST00000591111; = p.E16819K on NM_003319.4) | Missense Mutation (SNP) | VAF 23/91 reads (25%) | PolyPhen benign (0.266); catalogued as rs747699837, COSV60058890; called by muse, mutect2, varscan2
- TTN | c.35800G>A p.V11934M (on ENST00000591111; = p.V4510M on NM_003319.4) | Missense Mutation (SNP) | VAF 58/145 reads (40%) | PolyPhen probably damaging (0.986); catalogued as COSV59869581, COSV60303152; called by muse, mutect2, varscan2
- UNC13C | c.5614G>A p.G1872R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52917762; called by muse, mutect2, varscan2
- USF3 | c.3008G>A p.G1003D | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV100325693; called by muse, mutect2, varscan2
- USF3 | c.3007G>A p.G1003S | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.104); catalogued as rs1282022484, COSV100325695; called by muse, mutect2, varscan2
- ZER1 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV52568286; called by muse, mutect2, varscan2
- ZNF215 | c.1162T>C p.F388L | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53494698; called by muse, mutect2, varscan2
- ZNF483 | c.1775C>T p.S592L | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV58517085; called by muse, mutect2, varscan2
- ZNF521 | c.1790A>G p.N597S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.083); catalogued as rs1407019635, COSV64131262; called by muse, mutect2, varscan2
- ZNF532 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV60175278; called by muse, mutect2, varscan2
- ZNF536 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.415); catalogued as rs774965623, COSV62833030; called by muse, mutect2, varscan2
- ZNF605 | c.1576A>T p.I526F | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV59159981; called by muse, mutect2, varscan2
- ZNF804A | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56468497; called by muse, mutect2, varscan2
- ACACA | c.5245C>T p.P1749S | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C17orf98 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- IGHV3-30 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 112/1450 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); called by muse, mutect2
- TALDO1 | c.40del p.A14Rfs*35 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- TRAV20 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ACOXL | c.873G>A p.L291= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV67738162; called by muse, mutect2, varscan2
- ADGRB2 | c.4374C>T p.S1458= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV57073562, COSV57078222; called by muse, mutect2, varscan2
- ADGRF5 | c.3741C>T p.F1247= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as COSV51939286; called by muse, mutect2, varscan2
- ALDH16A1 | c.1524C>T p.L508= | Silent (SNP) | VAF 60/147 reads (41%) | catalogued as rs749754755, COSV53196457; called by muse, mutect2, varscan2
- ANKRD30A | c.3774G>A p.R1258= (on ENST00000611781; = p.R1202= on NM_052997.2) | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV64606841; called by muse, mutect2, varscan2
- BEND4 | c.1353C>T p.R451= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV72469371; called by muse, mutect2, varscan2
- C17orf98 | c.51G>A p.L17= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs753994511; called by muse, mutect2, varscan2
- CCDC141 | c.3723C>T p.S1241= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV55371415, COSV99836033; called by muse, mutect2, varscan2
- CYP4B1 | c.1326C>T p.A442= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV54725803; called by muse, mutect2, varscan2
- DNAH2 | c.8487C>T p.F2829= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV66725965; called by muse, mutect2, varscan2
- DOCK8 | c.3402C>T p.S1134= | Silent (SNP) | VAF 44/127 reads (35%) | catalogued as COSV101210045; called by muse, mutect2, varscan2
- DRD1 | c.984C>T p.P328= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as rs141925440; called by muse, mutect2, varscan2
- FAM193B | c.363C>T p.L121= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as COSV61558816; called by muse, mutect2, varscan2
- FLOT2 | c.306C>T p.V102= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as rs1284044927, COSV67529458; called by muse, mutect2, varscan2
- FOXP1 | c.126G>A p.P42= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as rs762082081, COSV59527025; ClinVar: likely benign; called by muse, mutect2, varscan2
- GMPPB | c.672C>T p.D224= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs1247769949, COSV100246717; called by muse, mutect2, varscan2
- GRM3 | c.1407C>T p.F469= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100862773; called by muse, mutect2
- HECW1 | c.3138C>T p.F1046= | Silent (SNP) | VAF 53/233 reads (23%) | catalogued as COSV67824484, COSV67838778; called by muse, mutect2, varscan2
- HRG | c.282C>T p.S94= | Silent (SNP) | VAF 55/187 reads (29%) | catalogued as rs765537265, COSV51647888; called by muse, mutect2, varscan2
- KCNA3 | c.1710G>A p.K570= | Silent (SNP) | VAF 58/153 reads (38%) | catalogued as COSV63902498, COSV63902626; called by muse, mutect2, varscan2
- LANCL1 | c.996C>T p.F332= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV99286445; called by muse, mutect2, varscan2
- MAGEA4 | c.474C>T p.S158= | Silent (SNP) | VAF 73/164 reads (45%) | catalogued as COSV52342925; called by muse, mutect2, varscan2
- MBD5 | c.3792C>T p.F1264= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV68696409; called by muse, mutect2, varscan2
- MRGPRX1 | c.108C>T p.I36= | Silent (SNP) | VAF 54/244 reads (22%) | catalogued as COSV57107605, COSV57107683; called by muse, mutect2
- MYH4 | c.5086C>T p.L1696= | Silent (SNP) | VAF 49/148 reads (33%) | catalogued as COSV55125034; called by muse, mutect2, varscan2
- NCF2 | c.477C>T p.I159= | Silent (SNP) | VAF 89/346 reads (26%) | catalogued as rs369845453, COSV62315185; called by muse, mutect2, varscan2
- OR2C3 | c.420G>A p.Q140= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV63575920, COSV63576078; called by muse, mutect2, varscan2
- OR2T27 | c.147C>T p.I49= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV61283421; called by muse, mutect2, varscan2
- OR2T33 | c.699G>A p.K233= | Silent (SNP) | VAF 31/135 reads (23%) | catalogued as rs767623642, COSV58818100, COSV58818310; called by muse, mutect2, varscan2
- OR3A2 | c.711C>T p.I237= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs867882973, COSV68694903; called by muse, varscan2
- PCDHGA3 | c.841C>T p.L281= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV54019731, COSV99548523; called by muse, mutect2, varscan2
- PDCD6IP | c.714C>T p.P238= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs761343613, COSV56245370; called by muse, mutect2, varscan2
- PGBD1 | c.1356C>T p.V452= | Silent (SNP) | VAF 96/275 reads (35%) | catalogued as rs1457642354, COSV52555846; called by muse, mutect2, varscan2
- RAI2 | c.1068C>T p.P356= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV58966054; called by muse, mutect2, varscan2
- RGS22 | c.81C>T p.F27= | Silent (SNP) | VAF 37/137 reads (27%) | catalogued as COSV62661491, COSV62666829; called by muse, mutect2, varscan2
- RWDD1 | c.423C>T p.F141= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV63972445; called by muse, mutect2, varscan2
- SDK2 | c.6216C>T p.S2072= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV66195383; called by muse, mutect2, varscan2
- SERPINA6 | c.585C>T p.L195= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as rs758836616, COSV58587293; called by muse, mutect2, varscan2
- SIPA1L2 | c.1581C>T p.S527= | Silent (SNP) | VAF 126/545 reads (23%) | catalogued as COSV53398537; called by muse, mutect2, varscan2
- SLC30A9 | c.1500T>G p.V500= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV52558997; called by muse, mutect2, varscan2
- SNTB1 | c.657C>T p.S219= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as COSV67328837; called by muse, mutect2, varscan2
- SORBS2 | c.1143C>T p.S381= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV53013272; called by muse, mutect2, varscan2
- TEX55 | c.195C>T p.S65= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV55212757, COSV99817568; called by muse, mutect2, varscan2
- TMEM200A | c.111G>A p.K37= | Silent (SNP) | VAF 50/139 reads (36%) | catalogued as COSV51658676; called by muse, mutect2, varscan2
- TMPRSS11A | c.255G>A p.V85= | Silent (SNP) | VAF 46/149 reads (31%) | catalogued as COSV58360819; called by muse, mutect2, varscan2
- TRHR | c.546G>A p.K182= | Silent (SNP) | VAF 35/139 reads (25%) | catalogued as COSV61236214; called by muse, mutect2, varscan2
- TRPC7 | c.504C>T p.I168= | Silent (SNP) | VAF 48/189 reads (25%) | catalogued as rs1178142311, COSV61462917; called by muse, mutect2, varscan2
- USH2A | c.15534G>A p.E5178= | Silent (SNP) | VAF 57/130 reads (44%) | catalogued as rs762874407, COSV52069184, COSV52070017; called by muse, mutect2, varscan2
- ZC3H10 | c.1224C>T p.I408= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs759128565, COSV57769866; called by muse, mutect2, varscan2
- ZDBF2 | c.4203G>A p.K1401= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV65629565; called by muse, mutect2, varscan2
- ZNF804A | c.636C>T p.I212= | Silent (SNP) | VAF 36/140 reads (26%) | catalogued as rs546038601, COSV56440951, COSV56447572; called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 8/56 reads (14%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- PARP15 | c.772-10C>T | Intron (SNP) | VAF 23/81 reads (28%) | catalogued as COSV100117178; called by muse, mutect2, varscan2
- RPL23AP42 | n.335C>T | RNA (SNP) | VAF 32/122 reads (26%) | called by muse, mutect2, varscan2
